Somatic mutation profile of tumor specimen TCGA-IN-A6RL-01A (aliquot TCGA-IN-A6RL-01A-11D-A32N-08) from TCGA case TCGA-IN-A6RL, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; Tumor grade: G2; Age at diagnosis: 84.3 years (30,783 days).
Specimen TCGA-IN-A6RL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 819d54e5-a48c-43a4-88f0-7ff7df08f499.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IN-A6RL-10A (Blood Derived Normal), aliquot TCGA-IN-A6RL-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a193a766-9452-4d30-8af4-5659f3881725

The open-access MAF lists 482 somatic variants for this specimen: 359 protein-altering or splice-affecting, 105 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 314, Silent 105, Nonsense Mutation 22, Intron 7, In Frame Del 6, Frame Shift Del 6, Splice Site 5, RNA 4, Frame Shift Ins 4, 5'UTR 3, 3'UTR 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 27/44 reads (61%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.87A>C p.E29D | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); catalogued as COSV100735682; called by muse, mutect2, varscan2
- ACADM | c.1104A>C p.L368F | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.214); catalogued as COSV100897593, COSV63721301; called by muse, mutect2, varscan2
- ACKR1 | c.877G>T p.A293S | Missense Mutation (SNP) | VAF 29/554 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV63673108; called by muse, mutect2
- ADAM2 | c.1142dup p.K382Qfs*8 | Frame Shift Ins (INS) | VAF 12/71 reads (17%) | catalogued as rs774922870; called by mutect2, pindel, varscan2
- ADGRG6 | c.1736A>G p.N579S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs1315377116, COSV99745851; called by muse, mutect2, varscan2
- AFF3 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780991519, COSV57843059; called by muse, mutect2, varscan2
- AHNAK | c.15572C>T p.A5191V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.339); catalogued as COSV99945653; called by muse, mutect2, varscan2
- AIM2 | c.457T>C p.C153R | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100931027; called by muse, mutect2, varscan2
- AKT3 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 7/120 reads (6%) | catalogued as COSV99794258; called by muse, mutect2
- ALK | c.4070C>A p.P1357H | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66591901; called by muse, varscan2
- AMPD1 | c.1544T>A p.I515N | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100814818; called by muse, mutect2, varscan2
- AMPH | c.2007G>T p.K669N | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100340969; called by muse, mutect2, varscan2
- ANK2 | c.2987G>T p.R996L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99999845; called by muse, mutect2, varscan2
- ANKRD13A | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 53/115 reads (46%) | catalogued as COSV99923842; called by muse, mutect2, varscan2
- ANKRD55 | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV100591065; called by muse, mutect2, varscan2
- ANKS4B | c.79C>A p.L27I | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV100289707; called by muse, mutect2
- ANXA9 | c.472+1G>C p.X158_splice | Splice Site (SNP) | VAF 9/73 reads (12%) | catalogued as COSV100929061; called by muse, mutect2, varscan2
- APPBP2 | c.1387C>A p.L463I | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV99319460; called by muse, mutect2, varscan2
- AQP12B | c.338C>A p.A113D (on ENST00000621682; = p.A125D on NM_001102467.2) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV101315843; called by muse, mutect2, varscan2
- ARID2 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100535437; called by muse, mutect2, varscan2
- ARIH1 | c.950G>A p.C317Y | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101158587; called by muse, mutect2, varscan2
- ASAP1 | c.1453G>C p.G485R | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100726846; called by muse, mutect2
- ASTN2 | c.3093G>T p.M1031I (on ENST00000313400 / NM_001365069.1; = p.M980I on NM_014010.5) | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1233724878, COSV99940275; called by muse, mutect2, varscan2
- ATP1A4 | c.2611G>T p.G871* | Nonsense Mutation (SNP) | VAF 18/170 reads (11%) | catalogued as COSV100927444; called by muse, mutect2
- ATP7B | c.1930A>G p.K644E | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV99666062; called by muse, mutect2, varscan2
- ATP8B2 | c.2411A>G p.E804G (on ENST00000672630; = p.E771G on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV100527663; called by muse, mutect2, varscan2
- BEST3 | c.67A>G p.K23E | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as COSV99876084; called by muse, mutect2, varscan2
- BLZF1 | c.327C>A p.F109L | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV100250489, COSV61394965; called by muse, mutect2, varscan2
- BMPR1A | c.1405G>C p.D469H | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100923320, COSV64404818; called by muse, mutect2, varscan2
- BRCA2 | c.8084C>A p.S2695* | Nonsense Mutation (SNP) | VAF 65/130 reads (50%) | catalogued as CM119496, COSV66456629; called by muse, mutect2, varscan2
- BRF1 | c.728G>A p.R243K | Missense Mutation (SNP) | VAF 48/566 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as rs587707880, COSV100526839; called by muse, mutect2
- BRINP3 | c.926C>A p.T309N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV100818376; called by muse, mutect2, varscan2
- BRPF1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100121103; called by muse, mutect2, varscan2
- BSN | c.9462G>T p.E3154D | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV99607337; called by muse, mutect2, varscan2
- C12orf4 | c.780T>G p.I260M | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.104); catalogued as rs1396601727, COSV99712557; called by muse, mutect2
- C14orf119 | c.117G>T p.M39I | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.31); catalogued as COSV99399081; called by muse, mutect2
- C14orf93 | c.323C>G p.P108R | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.134); catalogued as rs1326709817; called by muse, mutect2
- C1QTNF8 | c.472T>C p.C158R | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100116353; called by muse, mutect2, varscan2
- CABS1 | c.560A>G p.D187G | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs773257575, COSV99908946; called by muse, mutect2, varscan2
- CACNA1D | c.782T>C p.L261P | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99856652; called by muse, mutect2, varscan2
- CACNA1D | c.6388C>G p.L2130V (on ENST00000350061 / NM_001128840.3; = p.L2150V on NM_000720.4) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.01); catalogued as COSV99856655; called by muse, mutect2
- CACNA2D3 | c.391T>G p.F131V | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); catalogued as COSV99870501; called by muse, mutect2, varscan2
- CADPS | c.1226G>A p.G409D | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV51875785; called by muse, mutect2
- CCDC141 | c.2601C>A p.N867K | Missense Mutation (SNP) | VAF 17/342 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99836186; called by muse, mutect2
- CCDC171 | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143245137; called by muse, mutect2, varscan2
- CCER1 | c.545G>C p.G182A | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100726945; called by muse, mutect2
- CCL22 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.16); catalogued as rs151094699; called by muse, mutect2, varscan2
- CCR9 | c.450G>T p.Q150H (on ENST00000357632 / NM_031200.3; = p.Q138H on NM_006641.4) | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.33); catalogued as COSV100591599, COSV62940626; called by muse, mutect2
- CD33 | c.366A>C p.R122S | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.204); catalogued as COSV99220068; called by muse, mutect2, varscan2
- CD40LG | c.383G>C p.S128T | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV101033430; called by muse, mutect2
- CDH3 | c.2003T>G p.F668C | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99867581; called by muse, mutect2, varscan2
- CDK12 | c.2776C>A p.L926I | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV71000187; called by muse, mutect2
- CDK2 | c.750A>C p.K250N | Missense Mutation (SNP) | VAF 141/323 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as COSV99906664; called by muse, mutect2, varscan2
- CENPK | c.791T>C p.L264S | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99669361; called by muse, mutect2
- CFAP20 | c.197A>C p.K66T | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as rs954612366, COSV99343384; called by muse, mutect2
- CFHR2 | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV100804240; called by muse, mutect2, varscan2
- CGNL1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs370543863; called by muse, mutect2, varscan2
- CLIP2 | c.2726T>C p.L909P | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56288586; called by muse, mutect2
- CNGA2 | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100323383; called by muse, mutect2, varscan2
- CNTRL | c.6556C>G p.L2186V | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV99441195; called by muse, mutect2
- CPEB2 | c.2306G>T p.R769L | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52595625, COSV99469947; called by muse, mutect2, varscan2
- CR1 | c.3346A>G p.T1116A | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100887398; called by muse, mutect2, varscan2
- CRTAM | c.34T>A p.F12I | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV99911777; called by muse, mutect2, varscan2
- CSF1R | c.1754G>A p.G585D | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99640818; called by muse, mutect2, varscan2
- CSMD1 | c.8246T>G p.F2749C (on ENST00000520002; = p.F2748C on NM_033225.6) | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.353); catalogued as COSV100144123; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99599773; called by muse, mutect2, varscan2
- CUX2 | c.2824A>G p.S942G | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV99918663; called by muse, varscan2
- CXADR | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV99515022; called by muse, mutect2, varscan2
- CYP2A13 | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV100386634; called by muse, mutect2
- DACH2 | c.626T>G p.L209R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64173392, COSV64179776; called by muse, mutect2, varscan2
- DAGLB | c.323A>G p.E108G | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99765666; called by muse, mutect2
- DCLK1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55214935; called by muse, mutect2, varscan2
- DDX4 | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.218); catalogued as COSV100737312; called by muse, mutect2, varscan2
- DEDD | c.285C>A p.H95Q | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV100919027; called by muse, mutect2, varscan2
- DHCR7 | c.411A>T p.A137= | Splice Region (SNP) | VAF 11/30 reads (37%) | catalogued as CS073461, COSV100831723; called by muse, mutect2, varscan2
- DHX16 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as COSV100905134; called by muse, mutect2, varscan2
- DNAAF3 | c.1472A>C p.E491A (on ENST00000524407 / NM_001256715.2; = p.E538A on NM_178837.4) | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.187); catalogued as COSV100787854; called by muse, mutect2, varscan2
- DNAH10 | c.11576A>G p.N3859S (on ENST00000409039; = p.N3798S on NM_207437.3) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV101291994; called by muse, mutect2, varscan2
- DNAH11 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as rs753634502, COSV100177264; ClinVar: uncertain significance; called by muse, varscan2
- DNAH17 | c.10953C>A p.Y3651* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV101101492; called by muse, mutect2, varscan2
- DNAH5 | c.11888C>G p.S3963W | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54214570, COSV99445303; called by muse, mutect2, varscan2
- DNAJA2 | c.625A>C p.K209Q | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100398785; called by muse, mutect2
- DOCK4 | c.5134G>T p.E1712* | Nonsense Mutation (SNP) | VAF 8/150 reads (5%) | catalogued as COSV101447784; called by muse, mutect2
- DSCAML1 | c.3519G>T p.E1173D (on ENST00000321322; = p.E1113D on NM_020693.4) | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.805); catalogued as rs1464314543, COSV100354656; called by muse, mutect2, varscan2
- DSP | c.5011G>C p.E1671Q | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV101131184; called by muse, mutect2, varscan2
- DYNLRB1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); catalogued as COSV100307709; called by muse, mutect2, varscan2
- DYRK1A | c.100A>G p.M34V | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.267); catalogued as COSV100117473; called by muse, mutect2
- DYSF | c.6019G>A p.D2007N | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs748202120, COSV99244463; called by mutect2, varscan2
- DZIP3 | c.2710C>A p.Q904K | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.777); catalogued as COSV100847643; called by muse, mutect2, varscan2
- EFCAB3 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100540038; called by muse, mutect2
- EIF4G3 | c.1381T>C p.C461R | Missense Mutation (SNP) | VAF 30/319 reads (9%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.062); catalogued as COSV99943277; called by muse, mutect2
- EPB41L1 | c.344A>T p.K115I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99148988; called by muse, mutect2
- EPRS1 | c.4430A>C p.K1477T | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859314; called by muse, mutect2, varscan2
- ERRFI1 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 92/192 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV101087969; called by muse, mutect2, varscan2
- FAM135B | c.4210T>G p.Y1404D | Missense Mutation (SNP) | VAF 109/287 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99419182; called by muse, mutect2, varscan2
- FAM221B | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 42/262 reads (16%) | catalogued as COSV100941272, COSV65074820; called by muse, varscan2
- FAM47C | c.1836G>T p.E612D | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100792290; called by muse, varscan2
- FANCB | c.545T>G p.V182G | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV100146384; called by muse, mutect2, varscan2
- FBN2 | c.6319A>C p.N2107H | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.204); catalogued as COSV99325075; called by muse, mutect2, varscan2
- FBXL7 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.072); catalogued as COSV100309107, COSV61646956; called by muse, mutect2, varscan2
- FER | c.2300A>G p.Q767R | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99811665; called by muse, mutect2, varscan2
- FMO4 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.639); catalogued as COSV100882023, COSV63000828; called by muse, mutect2, varscan2
- FRMD3 | c.674A>G p.H225R | Missense Mutation (SNP) | VAF 79/284 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100418253; called by muse, mutect2, varscan2
- FRMPD4 | c.3350G>T p.R1117I | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as COSV66216459; called by muse, mutect2, varscan2
- FRYL | c.3685C>T p.Q1229* | Nonsense Mutation (SNP) | VAF 18/151 reads (12%) | catalogued as COSV99975829; called by muse, mutect2, varscan2
- FYB2 | c.1859A>G p.N620S | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV100599221; called by muse, mutect2
- GABRG1 | c.707A>C p.Y236S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); catalogued as COSV99777432; called by muse, mutect2
- GFRA4 | c.517C>T p.R173C (on ENST00000319242 / NM_145762.3; = p.S146= on NM_022139.4) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs1396206099, COSV99293840; called by muse, mutect2, varscan2
- GID8 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.08); catalogued as COSV99824039; called by muse, mutect2, varscan2
- GIGYF1 | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV99308822; called by muse, mutect2, varscan2
- GIMAP1 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs1448647168, COSV56188747; called by muse, mutect2, varscan2
- GNPNAT1 | c.28G>C p.D10H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV99369445; called by muse, mutect2, varscan2
- GOPC | c.544T>A p.L182M | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.254); catalogued as COSV99270697; called by muse, mutect2, varscan2
- GPI | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100731440; called by muse, mutect2
- GPR149 | c.955A>G p.K319E | Missense Mutation (SNP) | VAF 39/333 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1165049083, COSV101078123; called by muse, mutect2, varscan2
- GRIK5 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as rs12609687, COSV99490015; called by mutect2, varscan2
- GRM1 | c.328T>G p.W110G | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99264159; called by muse, mutect2, varscan2
- GSPT2 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 10/19 reads (53%) | catalogued as COSV100467915, COSV61213743; called by muse, mutect2, varscan2
- H2AJ | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100797611; called by muse, mutect2, varscan2
- HAP1 | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs781937062, COSV57878182; called by muse, mutect2, varscan2
- HEATR1 | c.3967A>G p.I1323V | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.439); catalogued as COSV63982114; called by muse, mutect2, varscan2
- HERC2 | c.1834A>C p.S612R | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99871131; called by muse, mutect2
- HOXA4 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57825075; called by muse, mutect2, varscan2
- HPSE2 | c.1333T>C p.S445P | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100985015; called by muse, mutect2, varscan2
- HSD11B1 | c.561G>T p.K187N | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM111741, COSV99807898; called by muse, mutect2, varscan2
- HYOU1 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 11/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101345543; called by muse, mutect2
- IFRD1 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1250996142, COSV50043641; called by muse, mutect2, varscan2
- IGHE | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368011020; called by muse, mutect2, varscan2
- IKZF2 | c.864G>C p.K288N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100563210; called by muse, mutect2
- IQSEC3 | c.2785C>G p.Q929E (on ENST00000538872 / NM_001170738.2; = p.Q626E on NM_015232.1) | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100406835; called by muse, mutect2, varscan2
- ISLR | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.876); catalogued as rs1233443000, COSV51433274; called by muse, mutect2, varscan2
- ITFG1 | c.1046T>C p.V349A | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100278375; called by muse, mutect2, varscan2
- ITGB4 | c.767C>G p.T256S | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV52322489, COSV99563421; called by muse, mutect2, varscan2
- ITIH6 | c.2426G>T p.R809I | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99512856; called by muse, mutect2, varscan2
- JHY | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 11/216 reads (5%) | catalogued as COSV99912764, COSV99913810; called by muse, mutect2
- KCNA10 | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs755353258, COSV100871396; called by muse, mutect2, varscan2
- KCNT2 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV99651630; called by muse, mutect2, varscan2
- KIAA1210 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV68179910; called by muse, mutect2, varscan2
- KLHL42 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 52/420 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.279); catalogued as rs1482201859, COSV67145579; called by muse, varscan2
- KLK11 | c.104T>G p.I35S (on ENST00000594768 / NM_144947.3; = p.I3S on NM_006853.3) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV99141798; called by muse, mutect2
- KMT2C | c.14343+2T>C p.X4781_splice | Splice Site (SNP) | VAF 38/99 reads (38%) | catalogued as COSV100067218; called by muse, mutect2, varscan2
- KMT2C | c.4184A>G p.Y1395C | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100067226; called by muse, mutect2, varscan2
- KRTAP10-12 | c.474G>C p.K158N | Missense Mutation (SNP) | VAF 40/485 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV100551965; called by muse, mutect2
- KRTAP10-3 | c.155G>C p.C52S | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs1555920419, COSV100551964; called by muse, mutect2
- LGI2 | c.950A>T p.D317V | Missense Mutation (SNP) | VAF 57/229 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.649); catalogued as COSV101180755; called by muse, mutect2, varscan2
- LGI2 | c.242T>G p.F81C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101180756; called by muse, mutect2, varscan2
- LILRB4 | c.551C>A p.P184H | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99553503, COSV99554233; called by muse, mutect2
- LRP1B | c.11437G>T p.G3813* | Nonsense Mutation (SNP) | VAF 9/112 reads (8%) | catalogued as COSV101252880; called by muse, mutect2
- LRP5 | c.2659G>A p.D887N | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99591447; called by muse, mutect2, varscan2
- LRRK2 | c.7133A>G p.K2378R | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV54153353; called by muse, mutect2, varscan2
- LYST | c.7370C>A p.S2457Y | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs764859264, COSV101088260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LYZL2 | c.224A>C p.K75T (on ENST00000375318; = p.K29T on NM_183058.3) | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as COSV100940524; called by muse, mutect2, varscan2
- LZTR1 | c.183C>A p.D61E | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.976); catalogued as COSV99301313; called by muse, mutect2, varscan2
- MAF1 | c.141C>G p.F47L | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV100075321; called by muse, mutect2
- MAGEC1 | c.1853G>T p.G618V | Missense Mutation (SNP) | VAF 149/619 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as COSV99594880; called by muse, mutect2, varscan2
- MAGI1 | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770193154, COSV58322664; called by muse, mutect2, varscan2
- MARS2 | c.785T>C p.L262S | Missense Mutation (SNP) | VAF 77/147 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99986489; called by muse, mutect2, varscan2
- MATR3 | c.1435-1G>C p.X479_splice | Splice Site (SNP) | VAF 9/111 reads (8%) | catalogued as COSV100735107; called by muse, mutect2
- MC5R | c.113T>C p.I38T | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV100228932; called by muse, mutect2
- MEP1A | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.314); catalogued as COSV100042368; called by muse, mutect2, varscan2
- MGA | c.97A>T p.N33Y | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99578608; called by muse, mutect2
- MGAT2 | c.705G>A p.W235* | Nonsense Mutation (SNP) | VAF 9/196 reads (5%) | catalogued as COSV100023430; called by muse, mutect2
- MINPP1 | c.725A>C p.N242T | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100916748, COSV100916782; called by muse, mutect2
- MMP3 | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as rs1453941959, COSV100242671; called by muse, mutect2
- MOCS1 | c.1576C>G p.Q526E | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.555); catalogued as COSV99224662; called by muse, mutect2
- MORC1 | c.1834T>G p.F612V | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV99225136; called by muse, mutect2, varscan2
- MS4A13 | c.359T>G p.F120C | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100981036; called by muse, mutect2, varscan2
- MTR | c.1357T>G p.F453V | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100855246; called by muse, mutect2, varscan2
- MUC17 | c.6422C>T p.S2141L | Missense Mutation (SNP) | VAF 36/500 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV60284954; called by muse, mutect2
- MYH9 | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV53384978; called by muse, mutect2, varscan2
- MYO16 | c.218A>G p.D73G | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99193544; called by muse, mutect2, varscan2
- MYO3A | c.3910G>T p.E1304* | Nonsense Mutation (SNP) | VAF 8/156 reads (5%) | catalogued as COSV99778429; called by muse, mutect2
- MYO3B | c.3906T>G p.D1302E | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100509217; called by muse, mutect2
- MYO5A | c.738A>T p.K246N | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100697325; called by muse, mutect2, varscan2
- MYO7B | c.1400A>T p.Q467L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV101267884; called by muse, mutect2, varscan2
- MYOM2 | c.2929T>G p.L977V | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1365806865, COSV100036700; called by muse, mutect2, varscan2
- NALCN | c.1853A>G p.E618G | Missense Mutation (SNP) | VAF 142/238 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99213071; called by muse, mutect2, varscan2
- NAMPT | c.1104G>T p.M368I | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV99747651; called by muse, mutect2, varscan2
- NLRP4 | c.1967T>C p.V656A | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100015621; called by muse, mutect2, varscan2
- OBSCN | c.3616C>G p.L1206V | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99473038; called by muse, mutect2
- OR2G3 | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 15/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100180481; called by muse, mutect2
- OR2J3 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs764586770, COSV101013554, COSV65849478; called by muse, mutect2
- OR4N2 | c.202T>G p.F68V | Missense Mutation (SNP) | VAF 35/315 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.682); catalogued as COSV100269391; called by muse, mutect2
- OR51A7 | c.493A>G p.R165G | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs1421299183, COSV100834588; called by muse, mutect2
- OR51F2 | c.82T>A p.W28R | Missense Mutation (SNP) | VAF 73/279 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100437891; called by muse, mutect2, varscan2
- OR8D1 | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as rs1022927561, COSV63443316; called by muse, mutect2, varscan2
- OSBPL6 | c.2708A>G p.D903G | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as COSV99506593; called by muse, mutect2, varscan2
- OTOF | c.4872A>C p.K1624N (on ENST00000272371 / NM_194248.3; = p.K857N on NM_004802.4) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99716600; called by muse, mutect2
- PARN | c.397T>A p.Y133N | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100420656; called by muse, mutect2
- PAX3 | c.1247C>T p.T416I | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.616); catalogued as COSV100399054; called by muse, mutect2, varscan2
- PCDHA10 | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 11/259 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100247733; called by muse, mutect2
- PCDHA12 | c.1332G>T p.E444D | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.155); catalogued as COSV100247734; called by muse, mutect2, varscan2
- PCDHGA1 | c.790G>C p.V264L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.246); catalogued as COSV100965928; called by muse, mutect2, varscan2
- PCDHGC4 | c.728A>G p.Q243R | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs376101780; called by muse, mutect2, varscan2
- PCED1B | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV71395065; called by muse, mutect2, varscan2
- PDE3A | c.3258G>A p.W1086* | Nonsense Mutation (SNP) | VAF 8/141 reads (6%) | catalogued as COSV62978807; called by muse, mutect2
- PDZRN4 | c.3003G>T p.K1001N (on ENST00000402685 / NM_001164595.2; = p.K743N on NM_013377.4) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs559763667, COSV100113653, COSV54202377; called by mutect2, varscan2
- PEX5L | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 58/174 reads (33%) | catalogued as COSV55847021, COSV99827958; called by muse, mutect2, varscan2
- PGLYRP3 | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs748288161, COSV51948890; called by muse, mutect2, varscan2
- PIGG | c.1434G>C p.L478F (on ENST00000453061 / NM_001127178.3; = p.L470F on NM_017733.4) | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV99573628; called by muse, mutect2
- PITPNM2 | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99758338; called by muse, mutect2, varscan2
- PKM | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as COSV100064501; called by muse, mutect2, varscan2
- PLA2R1 | c.3769T>A p.F1257I | Missense Mutation (SNP) | VAF 77/159 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV99322212; called by muse, mutect2, varscan2
- PLCG2 | c.2604C>A p.N868K | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1131691537, COSV100842059; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCL1 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV101406795; called by muse, mutect2
- PLCZ1 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99855880; called by muse, mutect2
- PLEKHA8 | c.875A>G p.D292G | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV51649354; called by muse, mutect2
- POLE | c.6349A>G p.N2117D | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1555301269, COSV100265420; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLQ | c.6784A>G p.T2262A | Missense Mutation (SNP) | VAF 11/241 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99951642; called by muse, mutect2
- POMT1 | c.1972G>T p.E658* | Nonsense Mutation (SNP) | VAF 9/190 reads (5%) | catalogued as COSV100586075; called by muse, mutect2
- PREX1 | c.502G>T p.V168L | Missense Mutation (SNP) | VAF 24/410 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.136); catalogued as COSV100906183, COSV64253062; called by muse, mutect2
- PROKR2 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751875578, CM065402, COSV54087267, COSV54087377; called by muse, mutect2, varscan2
- PRRC2B | c.950G>T p.R317I | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100621449; called by muse, mutect2, varscan2
- PRSS36 | c.2218C>T p.L740F | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as COSV99191230; called by muse, mutect2
- PRSS38 | c.352G>C p.V118L | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.236); catalogued as COSV100816326, COSV64541047; called by muse, mutect2, varscan2
- PRUNE2 | c.3220A>G p.S1074G | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV100944234; called by muse, mutect2, varscan2
- PSD4 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.021); catalogued as COSV99830840; called by muse, mutect2
- PTCHD4 | c.2438C>T p.S813F | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59794829; called by muse, mutect2, varscan2
- PUM2 | c.2654G>A p.C885Y | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100163184; called by muse, mutect2
- RAP1GAP | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs771544929, COSV99264736; called by muse, mutect2
- RASGRF2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1305250577, COSV99428562; called by muse, mutect2, varscan2
- RB1CC1 | c.1674G>T p.W558C | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99206287; called by muse, mutect2, varscan2
- RB1CC1 | c.1673G>C p.W558S | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV99206305; called by muse, mutect2, varscan2
- RBBP6 | c.1959G>T p.K653N | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100154234; called by muse, mutect2, varscan2
- RBKS | c.19C>G p.P7A | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV100141956; called by muse, mutect2, varscan2
- RBM39 | c.146G>C p.R49T | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.879); catalogued as COSV99488261; called by muse, mutect2
- RBM48 | c.761A>C p.N254T | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV99720045; called by muse, mutect2, varscan2
- RBPJL | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs911393889, COSV59213109; called by muse, mutect2, varscan2
- RELN | c.3454G>A p.G1152S | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV100632530; called by muse, mutect2, varscan2
- REV3L | c.4249C>T p.P1417S | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100724882; called by muse, mutect2
- RORB | c.439G>A p.E147K (on ENST00000396204 / NM_001365023.1; = p.E136K on NM_006914.4) | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.03); catalogued as rs199713370, COSV65332744; called by muse, mutect2, varscan2
- RP1 | c.778A>G p.S260G | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV99606311; called by muse, mutect2, varscan2
- RP1L1 | c.2193C>A p.D731E | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV101222965; called by muse, mutect2
- RPAP1 | c.950C>A p.A317E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100426945; called by muse, mutect2, varscan2
- RRAGD | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100784502, COSV63268936; called by muse, mutect2, varscan2
- RUNDC3A | c.309A>C p.K103N | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV99841703; called by muse, mutect2
- SACS | c.7763T>G p.L2588R | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101207168, COSV101207176; called by muse, mutect2
- SALL2 | c.1837G>T p.G613* | Nonsense Mutation (SNP) | VAF 9/93 reads (10%) | catalogued as COSV100444124; called by muse, mutect2
- SCAMP3 | c.68A>G p.D23G | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100226590; called by muse, mutect2, varscan2
- SCMH1 | c.1360T>G p.C454G (on ENST00000326197 / NM_001031694.2; = p.C407G on NM_012236.4) | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100401372; called by muse, mutect2, varscan2
- SCN3A | c.5023T>A p.S1675T | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV99325719; called by muse, mutect2
- SCN5A | c.1179C>A p.F393L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CD024655, COSV100346561; called by muse, mutect2, varscan2
- SDK2 | c.3294G>T p.M1098I | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV101166851; called by muse, mutect2, varscan2
- SEMA3E | c.1265C>A p.P422Q | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100317346; called by muse, mutect2
- SIGLEC6 | c.643T>A p.C215S | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100585162; called by muse, mutect2, varscan2
- SIPA1L1 | c.2457G>T p.K819N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.351); catalogued as COSV100665154; called by muse, mutect2
- SKIV2L | c.3464A>G p.N1155S | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1445290831, COSV100514545; called by muse, mutect2, varscan2
- SLC16A12 | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100370453; called by muse, mutect2
- SLC25A14 | c.263T>G p.F88C | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV99502301; called by muse, mutect2, varscan2
- SLC25A31 | c.261G>T p.L87F | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV55417635, COSV99829221; called by muse, mutect2
- SLC28A2 | c.1648A>G p.T550A | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV100754623; called by muse, mutect2, varscan2
- SLC2A5 | c.1403T>G p.F468C | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101072618; called by muse, mutect2, varscan2
- SLC9B1 | c.1050G>T p.L350F | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99599202; called by muse, mutect2, varscan2
- SLCO3A1 | c.1900A>G p.K634E | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100574927; called by muse, mutect2, varscan2
- SLITRK6 | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 89/135 reads (66%) | SIFT tolerated (0.98); PolyPhen benign (0.425); catalogued as COSV101233234, COSV68391611; called by muse, mutect2, varscan2
- SMC3 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554882316, COSV100699787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMCO1 | c.522G>T p.K174N | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV100534850; called by muse, mutect2
- SOX14 | c.75G>T p.K25N | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100048051; called by muse, mutect2, varscan2
- SOX7 | c.147G>T p.M49I | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100448966; called by muse, mutect2, varscan2
- SPACA3 | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV99284107; called by muse, varscan2
- SPEF2 | c.3683A>C p.K1228T | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV100606360; called by muse, mutect2
- SSTR1 | c.136T>C p.S46P | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs777857855, COSV99942712; called by muse, mutect2, varscan2
- STAB1 | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs769945452, COSV58737280; called by mutect2, varscan2
- STAB2 | c.3065C>A p.T1022K | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.113); catalogued as COSV101185636; called by muse, mutect2, varscan2
- SUGP2 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 99/179 reads (55%) | catalogued as COSV100431479; called by muse, mutect2, varscan2
- SUSD1 | c.170G>T p.C57F | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs931464235, COSV100813171; called by muse, mutect2, varscan2
- SYNE1 | c.21175A>C p.N7059H (on ENST00000367255 / NM_182961.4; = p.N6988H on NM_033071.3) | Missense Mutation (SNP) | VAF 80/264 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99554046; called by muse, mutect2, varscan2
- SYNM | c.1626G>T p.L542F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100152435; called by muse, mutect2, varscan2
- SYT11 | c.862-1G>T p.X288_splice | Splice Site (SNP) | VAF 7/72 reads (10%) | catalogued as COSV100851277; called by muse, mutect2, varscan2
- TACC2 | c.1321T>A p.S441T | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100551593; called by muse, mutect2
- TAF1L | c.4166C>T p.P1389L | Missense Mutation (SNP) | VAF 83/288 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs753460641, COSV99644129; called by muse, mutect2, varscan2
- TBC1D2B | c.417G>T p.W139C | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100316843; called by muse, mutect2, varscan2
- TBC1D8 | c.2189A>G p.H730R | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV100964287; called by muse, mutect2
- TCF7L2 | c.770T>G p.L257R (on ENST00000355995 / NM_001367943.1; = p.L234R on NM_030756.5) | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99525290; called by muse, mutect2, varscan2
- TCOF1 | c.1222G>A p.E408K (on ENST00000377797 / NM_001135243.1; = p.E331K on NM_000356.4) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV100076875; called by muse, mutect2
- TECTA | c.3010A>T p.T1004S | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99878644; called by muse, mutect2, varscan2
- TECTA | c.3205A>G p.R1069G | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99878645; called by muse, mutect2, varscan2
- TECTB | c.931A>C p.S311R | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.022); catalogued as COSV101027636; called by muse, mutect2, varscan2
- TEKT1 | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as COSV100105950; called by muse, mutect2, varscan2
- TENM1 | c.1548G>A p.M516I | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100949090, COSV64441373; called by muse, mutect2, varscan2
- TEX2 | c.836A>G p.K279R | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99366806; called by muse, mutect2
- TKT | c.790A>C p.K264Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.188); catalogued as rs782480479, COSV56245178, COSV99964861; called by muse, mutect2
- TMCC3 | c.932T>G p.L311R | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99705222; called by muse, mutect2, varscan2
- TMEM245 | c.2306C>T p.T769I | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV65824949; called by muse, mutect2, varscan2
- TMEM266 | c.134T>C p.F45S | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); catalogued as COSV101189564; called by muse, mutect2, varscan2
- TMEM8B | c.1241A>T p.H414L | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100941526; called by muse, mutect2, varscan2
- TNFSF15 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV100928363; called by muse, mutect2
- TNRC6C | c.3468G>T p.Q1156H | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs987589824, COSV100049485, COSV56951838; called by muse, mutect2, varscan2
- TNXB | c.7131G>T p.K2377N (on ENST00000647633; = p.K2130N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100925899; called by muse, mutect2
- TOM1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 19/291 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285037301, COSV101146504; called by muse, mutect2
- TREML2 | c.172A>C p.I58L | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs1358241663, COSV101530141; called by muse, mutect2
- TRMT9B | c.1151C>A p.S384Y | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101501517; called by mutect2, varscan2
- TRPS1 | c.1094C>T p.S365F (on ENST00000220888 / NM_001330599.2; = p.S378F on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV55235651, COSV55267255; called by muse, mutect2, varscan2
- TSGA10 | c.1682G>A p.R561K | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs753449936, COSV100747437; called by muse, mutect2, varscan2
- TSNAXIP1 | c.782T>C p.F261S | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs949483574, COSV99534851; called by muse, mutect2
- TTN | c.79430G>A p.R26477H (on ENST00000591111; = p.R19053H on NM_003319.4) | Missense Mutation (SNP) | VAF 10/89 reads (11%) | PolyPhen probably damaging (0.982); catalogued as rs72648220, COSV100595003; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.2047C>A p.L683I | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100229267; called by muse, mutect2, varscan2
- USP6 | c.3593G>T p.R1198L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.41); catalogued as rs749335334, COSV100003075; called by muse, mutect2, varscan2
- VEZF1 | c.1409T>A p.V470D | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as COSV99365579; called by muse, mutect2, varscan2
- VPS39 | c.652G>T p.V218L (on ENST00000348544 / NM_001301138.2; = p.V207L on NM_015289.5) | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100528977; called by muse, mutect2
- WDR19 | c.3353C>A p.S1118Y | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.601); catalogued as COSV99975210; called by muse, mutect2, varscan2
- WIPF1 | c.1259C>A p.P420H | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99767965; called by muse, mutect2, varscan2
- XAF1 | c.539A>C p.K180T | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV100694973; called by muse, mutect2
- XIRP2 | c.7043C>T p.S2348L (on ENST00000628543; = p.S2523L on NM_152381.6) | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1456895639, COSV54712922; called by muse, mutect2, varscan2
- XRN2 | c.764T>A p.F255Y | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101017993; called by muse, mutect2, varscan2
- ZBTB33 | c.268A>C p.I90L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100434053; called by muse, mutect2, varscan2
- ZBTB48 | c.1011T>G p.H337Q | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100039486; called by muse, mutect2, varscan2
- ZC3H7B | c.455T>G p.V152G | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100687055; called by muse, mutect2, varscan2
- ZDHHC11 | c.636G>C p.K212N | Missense Mutation (SNP) | VAF 20/698 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as COSV99362247; called by muse, mutect2
- ZFR2 | c.2289G>T p.K763N | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as COSV99507005; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1910G>A p.C637Y | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99837438; called by muse, mutect2
- ZNF175 | c.1709C>A p.S570Y | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as COSV99219279; called by muse, mutect2
- ZNF181 | c.854T>A p.I285K | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as rs776981704, COSV101106182; called by muse, mutect2, varscan2
- ZNF223 | c.975C>A p.F325L | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101462601; called by muse, mutect2
- ZNF233 | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100492103; called by muse, mutect2, varscan2
- ZNF330 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV53707245; called by muse, mutect2
- ZNF331 | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.762); catalogued as rs1455741143, COSV99466874, COSV99467018; called by muse, mutect2
- ZNF432 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs550723796, COSV99659073; called by muse, mutect2
- ZNF462 | c.2117A>T p.K706I | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.473); catalogued as COSV99470825; called by muse, mutect2
- ZNF578 | c.1560T>G p.F520L | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV101405010; called by muse, mutect2, varscan2
- ZNF597 | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 135/278 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100071895; called by muse, mutect2, varscan2
- ZNF630 | c.541T>C p.C181R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.867); catalogued as COSV99332218; called by muse, mutect2, varscan2
- ZNF699 | c.174A>C p.L58= | Splice Region (SNP) | VAF 18/166 reads (11%) | catalogued as COSV100426820; called by muse, mutect2, varscan2
- ZNF710 | c.1965G>A p.M655I | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV99184086; called by muse, mutect2, varscan2
- ZNF749 | c.150G>A p.W50* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100494205; called by muse, mutect2, varscan2
- ZNF772 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV100582768; called by muse, mutect2
- ZNF808 | c.2400C>A p.F800L | Missense Mutation (SNP) | VAF 21/354 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100707795, COSV63119513; called by muse, mutect2
- ZNF99 | c.134T>C p.I45T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV101233715; called by muse, mutect2, varscan2
- ZSCAN21 | c.1016A>G p.K339R | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as COSV99460656; called by muse, mutect2, varscan2
- ABCA13 | c.1301A>C p.N434T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- BTG4 | c.563dup p.N189Efs*22 | Frame Shift Ins (INS) | VAF 25/127 reads (20%) | called by mutect2, pindel, varscan2
- CATSPER2 | c.1058_1059delinsC p.E353Afs*31 | Frame Shift Del (DEL) | VAF 7/57 reads (12%) | called by pindel, varscan2*
- CBX2 | c.1321_1333del p.E441Pfs*14 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel
- DAPK1 | c.1519_1545del p.K507_L515del | In Frame Del (DEL) | VAF 14/100 reads (14%) | called by mutect2, pindel
- EMSY | c.2427_2432del p.I809_Q810del | In Frame Del (DEL) | VAF 16/112 reads (14%) | called by mutect2, pindel, varscan2
- GNPDA2 | c.119_124+9del p.X40_splice | Splice Site (DEL) | VAF 10/76 reads (13%) | called by mutect2, pindel
- GRM5 | c.514T>C p.Y172H | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITPRID2 | c.2583C>A p.H861Q | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- KATNAL2 | c.296dup p.N99Kfs*2 (on ENST00000356157 / NM_001353899.1; = p.N27Kfs*2 on NM_031303.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 94/227 reads (41%) | called by mutect2, pindel, varscan2
- NCKAP5L | c.646_673del p.G216Sfs*22 | Frame Shift Del (DEL) | VAF 4/53 reads (8%) | called by mutect2, pindel
- NKAIN4 | c.540C>A p.F180L | Missense Mutation (SNP) | VAF 15/435 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); called by muse, mutect2
- OLFM4 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- PCDH9 | c.257dup p.T87Hfs*19 | Frame Shift Ins (INS) | VAF 44/95 reads (46%) | called by mutect2, pindel, varscan2
- PLCB3 | c.925_939del p.P309_L313del | In Frame Del (DEL) | VAF 38/145 reads (26%) | called by mutect2, pindel, varscan2
- POLD2 | c.1151_1153del p.C384del | In Frame Del (DEL) | VAF 22/120 reads (18%) | called by pindel, varscan2
- PRAMEF15 | c.1018C>A p.L340I | Missense Mutation (SNP) | VAF 46/717 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.408); called by muse, mutect2
- PRAMEF18 | c.261C>A p.C87* | Nonsense Mutation (SNP) | VAF 35/812 reads (4%) | called by muse, mutect2
- PRAMEF20 | c.122T>C p.M41T | Missense Mutation (SNP) | VAF 15/342 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.302); called by muse, mutect2
- PRKACA | c.850_864del p.N284_G288del | In Frame Del (DEL) | VAF 35/221 reads (16%) | called by mutect2, pindel, varscan2
- RAB33B | c.21_59del p.S8_S20del | In Frame Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- SMAD4 | c.1194_1225del p.W398Cfs*20 | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | called by mutect2, pindel
- SPATA31D1 | c.2347G>T p.D783Y | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); called by muse, mutect2
- SULF1 | c.1471_1517del p.N491* | Frame Shift Del (DEL) | VAF 26/104 reads (25%) | called by mutect2, pindel
- TJAP1 | c.1636C>A p.L546M (on ENST00000372445 / NM_001146016.1; = p.L536M on NM_080604.3) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TPTE | c.1486T>C p.F496L (on ENST00000618007 / NM_199261.4; = p.F478L on NM_199259.4) | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- TRAV40 | c.163_173del p.E55Qfs*23 | Frame Shift Del (DEL) | VAF 18/162 reads (11%) | called by mutect2, pindel
- TRDV1 | c.195G>T p.M65I | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- VDAC3 | c.338A>C p.K113T | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2
- ACOT12 | c.900T>C p.F300= | Silent (SNP) | VAF 15/162 reads (9%) | catalogued as COSV100296735; called by muse, mutect2
- ADGRL3 | c.3447T>G p.A1149= (on ENST00000506720 / NM_001322402.2; = p.A1081= on NM_015236.6) | Silent (SNP) | VAF 48/133 reads (36%) | catalogued as COSV101546865; called by muse, mutect2, varscan2
- AKAP6 | c.6336C>T p.Y2112= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV99798432; called by muse, mutect2
- AKR1D1 | c.276T>C p.N92= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as rs559543573, COSV99652838; called by muse, mutect2, varscan2
- ANK2 | c.579G>T p.L193= | Silent (SNP) | VAF 92/189 reads (49%) | catalogued as COSV99999843; called by muse, mutect2, varscan2
- APLNR | c.1110C>A p.I370= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as COSV99951253; called by muse, mutect2, varscan2
- ASAP1 | c.2967G>A p.L989= | Silent (SNP) | VAF 12/274 reads (4%) | catalogued as COSV63044494; called by muse, mutect2
- ATP2B4 | c.2883C>A p.T961= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as COSV100397095; called by muse, mutect2, varscan2
- C10orf62 | c.375C>T p.A125= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as rs747034275, COSV101035214; called by muse, mutect2, varscan2
- C16orf46 | c.1134G>A p.P378= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs377272864; called by muse, mutect2, varscan2
- CACNA1S | c.1075C>T p.L359= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as COSV100754666; called by muse, mutect2, varscan2
- CADPS | c.1227C>A p.G409= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as COSV99336002; called by muse, mutect2
- CFAP299 | c.621C>T p.D207= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV100811376; called by muse, mutect2, varscan2
- CHM | c.1632A>G p.P544= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100753027; called by muse, mutect2, varscan2
- CHML | c.435A>G p.L145= | Silent (SNP) | VAF 51/396 reads (13%) | catalogued as COSV100087035; called by muse, mutect2, varscan2
- CNOT1 | c.2667C>T p.N889= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as COSV99799286; called by muse, mutect2, varscan2
- COL2A1 | c.3354A>G p.K1118= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100475537; called by muse, mutect2, varscan2
- COL4A6 | c.2754A>C p.G918= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100563386; called by muse, mutect2, varscan2
- CTNNA1 | c.460C>T p.L154= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as COSV100242196; called by muse, mutect2, varscan2
- CYFIP2 | c.2202C>A p.I734= (on ENST00000616178 / NM_001291722.2; = p.I709= on NM_014376.4) | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100555666; called by muse, mutect2, varscan2
- CYLC1 | c.801T>C p.N267= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100254067; called by muse, mutect2, varscan2
- DAPK1 | c.132C>T p.I44= | Silent (SNP) | VAF 5/83 reads (6%) | catalogued as COSV63790312; called by muse, mutect2
- DDAH1 | c.585G>A p.Q195= | Silent (SNP) | VAF 25/238 reads (11%) | catalogued as COSV52306182, COSV99394613; called by muse, varscan2
- DNAH17 | c.3753G>A p.A1251= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs370307232; called by muse, mutect2, varscan2
- DNAH7 | c.7542A>G p.S2514= | Silent (SNP) | VAF 10/131 reads (8%) | catalogued as COSV100413869; called by muse, mutect2
- EFHB | c.1818T>C p.F606= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99859146; called by mutect2, varscan2
- EGFR | c.1893A>G p.P631= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs1332637770, COSV99286979; called by muse, mutect2, varscan2
- EIF2AK3 | c.1395T>C p.S465= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV100303456; called by muse, mutect2, varscan2
- ESAM | c.402A>G p.Q134= | Silent (SNP) | VAF 15/171 reads (9%) | catalogued as COSV99631630; called by muse, mutect2
- F11R | c.681G>A p.V227= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as COSV99230780; called by muse, mutect2, varscan2
- FAM234B | c.1611C>A p.A537= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV99545391; called by muse, mutect2, varscan2
- FASN | c.1974G>T p.V658= | Silent (SNP) | VAF 12/159 reads (8%) | catalogued as COSV100147332, COSV100147414; called by muse, mutect2
- FAT4 | c.4290T>C p.V1430= | Silent (SNP) | VAF 95/165 reads (58%) | catalogued as COSV101271916; called by muse, mutect2, varscan2
- FILIP1 | c.706C>T p.L236= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as rs373722500; called by muse, mutect2, varscan2
- FLNB | c.4095T>C p.V1365= | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as COSV55885585; called by muse, mutect2, varscan2
- GALNT9 | c.1767G>A p.G589= (on ENST00000328957 / NM_001122636.2; = p.G223= on NM_021808.3) | Silent (SNP) | VAF 75/113 reads (66%) | catalogued as COSV100201050; called by muse, mutect2, varscan2
- GAS2L2 | c.2229C>A p.P743= | Silent (SNP) | VAF 19/322 reads (6%) | called by muse, mutect2
- GRB10 | c.39T>C p.H13= | Silent (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- GTPBP8 | c.51T>G p.P17= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99868210; called by muse, mutect2
- IQGAP3 | c.342C>T p.A114= | Silent (SNP) | VAF 28/252 reads (11%) | catalogued as COSV100752069; called by muse, mutect2, varscan2
- ITFG2 | c.1269C>T p.A423= | Silent (SNP) | VAF 11/172 reads (6%) | catalogued as COSV99958000; called by muse, mutect2
- JAKMIP1 | c.1506C>T p.Y502= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as rs753975251, COSV51523247; called by muse, mutect2, varscan2
- KCNH5 | c.636T>C p.A212= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100525414; called by muse, mutect2, varscan2
- KIAA1549 | c.1527C>T p.A509= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs373138309, COSV99649848; called by muse, mutect2, varscan2
- KIAA2026 | c.2979A>C p.S993= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as COSV101198857; called by muse, mutect2, varscan2
- KLHL18 | c.153C>T p.A51= | Silent (SNP) | VAF 29/176 reads (16%) | catalogued as COSV99230538; called by muse, mutect2, varscan2
- KRT72 | c.1224T>C p.R408= | Silent (SNP) | VAF 12/225 reads (5%) | catalogued as rs1339108006, COSV99537056; called by muse, mutect2
- LIG4 | c.1929C>T p.H643= | Silent (SNP) | VAF 73/117 reads (62%) | catalogued as COSV100799704; called by muse, mutect2, varscan2
- LPCAT2 | c.276T>C p.P92= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as rs757732570, COSV100044448; called by muse, mutect2, varscan2
- LRRC2 | c.21C>A p.V7= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as COSV56125875; called by muse, mutect2, varscan2
- LRRC46 | c.297A>G p.Q99= | Silent (SNP) | VAF 22/291 reads (8%) | catalogued as COSV99273935; called by muse, mutect2
- LY9 | c.1947T>G p.P649= | Silent (SNP) | VAF 14/299 reads (5%) | catalogued as COSV54433350, COSV99626230; called by muse, mutect2
- MCHR1 | c.477C>A p.L159= | Silent (SNP) | VAF 15/151 reads (10%) | catalogued as COSV99967734; called by muse, mutect2, varscan2
- MICALL2 | c.708C>T p.F236= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1431368418, COSV52516263; called by muse, mutect2
- MINDY2 | c.1773A>G p.G591= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV100376279; called by muse, mutect2
- MST1R | c.1527A>G p.L509= | Silent (SNP) | VAF 14/145 reads (10%) | catalogued as COSV99617772; called by muse, mutect2
- MYH2 | c.4797C>A p.I1599= | Silent (SNP) | VAF 18/218 reads (8%) | catalogued as COSV55448107, COSV99819294; called by muse, mutect2
- MYLK | c.2682G>A p.Q894= | Silent (SNP) | VAF 13/166 reads (8%) | catalogued as COSV60618736; called by muse, mutect2
- MYO1D | c.2175G>A p.L725= | Silent (SNP) | VAF 11/305 reads (4%) | catalogued as COSV100555082; called by muse, mutect2
- NAA30 | c.681C>A p.I227= | Silent (SNP) | VAF 30/392 reads (8%) | catalogued as COSV100035765; called by muse, mutect2
- NKG7 | c.426C>A p.L142= | Silent (SNP) | VAF 19/259 reads (7%) | catalogued as COSV99389797; called by muse, mutect2
- NLRP9 | c.2439T>C p.D813= | Silent (SNP) | VAF 12/165 reads (7%) | catalogued as COSV100242600; called by muse, mutect2
- OPRK1 | c.117C>T p.N39= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs200733685, COSV55574801; ClinVar: likely benign; called by mutect2, varscan2
- OR51A7 | c.117C>A p.I39= | Silent (SNP) | VAF 57/109 reads (52%) | catalogued as COSV100834587, COSV63788400; called by muse, mutect2, varscan2
- OR6K6 | c.777A>G p.E259= (on ENST00000368144; = p.E235= on NM_001005184.1) | Silent (SNP) | VAF 14/213 reads (7%) | catalogued as COSV100933682; called by muse, mutect2
- PCDHB1 | c.1998C>G p.G666= | Silent (SNP) | VAF 24/178 reads (13%) | catalogued as COSV100128028; called by muse, mutect2, varscan2
- PCDHB7 | c.1884G>A p.R628= | Silent (SNP) | VAF 16/612 reads (3%) | catalogued as rs1376895433; called by muse, mutect2
- PCDHGA2 | c.2145G>A p.R715= | Silent (SNP) | VAF 25/208 reads (12%) | catalogued as COSV99531101; called by muse, mutect2, varscan2
- PHF1 | c.720C>G p.G240= | Silent (SNP) | VAF 71/191 reads (37%) | catalogued as COSV100992571; called by muse, mutect2, varscan2
- PIP5K1C | c.474C>T p.S158= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV100094966; called by muse, mutect2, varscan2
- PKLR | c.732C>T p.G244= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as rs1334671343, COSV61361027; called by muse, mutect2
- PPIL1 | c.204A>T p.T68= | Silent (SNP) | VAF 18/264 reads (7%) | catalogued as COSV100839345; called by muse, mutect2
- PPP1R12C | c.639G>A p.L213= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV54736212; called by muse, mutect2, varscan2
- QRICH2 | c.564A>G p.R188= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as COSV99428804; called by muse, mutect2, varscan2
- RETSAT | c.96T>G p.P32= | Silent (SNP) | VAF 59/268 reads (22%) | catalogued as COSV99805873; called by muse, mutect2, varscan2
- RNF182 | c.306A>T p.P102= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as COSV101337844; called by muse, mutect2, varscan2
- RUSC2 | c.4104G>A p.S1368= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs796830914, COSV63427610; called by mutect2, varscan2
- RYR3 | c.1119T>C p.T373= | Silent (SNP) | VAF 43/132 reads (33%) | catalogued as rs760206490, COSV101212027, COSV101215037, COSV66780594; called by muse, mutect2, varscan2
- SCUBE3 | c.2874C>T p.H958= | Silent (SNP) | VAF 10/272 reads (4%) | catalogued as rs1466738214, COSV99233947; called by muse, mutect2
- SEC14L4 | c.471G>T p.G157= | Silent (SNP) | VAF 32/153 reads (21%) | catalogued as COSV99742675; called by muse, mutect2, varscan2
- SERTAD4 | c.795C>A p.I265= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs1281886340, COSV100882583; called by muse, mutect2, varscan2
- SLAMF7 | c.111G>T p.V37= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV100833198; called by muse, mutect2, varscan2
- SLC24A5 | c.1269A>G p.A423= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as COSV99981208; called by muse, mutect2
- SLC5A11 | c.220T>C p.L74= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV100762678; called by muse, mutect2, varscan2
- SLC5A4 | c.354T>C p.P118= | Silent (SNP) | VAF 24/220 reads (11%) | catalogued as rs746711017, COSV99831681; called by muse, mutect2
- SLF2 | c.1563C>T p.H521= | Silent (SNP) | VAF 14/200 reads (7%) | catalogued as COSV99488502; called by muse, mutect2
- ST6GAL2 | c.933C>T p.G311= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs561108366, COSV100867683; called by muse, mutect2, varscan2
- STAT1 | c.1941C>T p.I647= | Silent (SNP) | VAF 15/172 reads (9%) | catalogued as COSV100738455, COSV63117464; called by muse, mutect2
- SUMF2 | c.429A>G p.A143= (on ENST00000652303; = p.A124= on NM_015411.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 90/243 reads (37%) | catalogued as COSV51915999; called by muse, mutect2, varscan2
- SYNE3 | c.2292G>A p.G764= | Silent (SNP) | VAF 87/333 reads (26%) | catalogued as rs1387803439, COSV100515648; called by muse, mutect2, varscan2
- TBC1D9 | c.261C>T p.I87= | Silent (SNP) | VAF 9/145 reads (6%) | catalogued as COSV101464268; called by muse, mutect2
- TECTA | c.4227C>T p.D1409= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs369626875; called by muse, mutect2, varscan2
- TEX15 | c.730C>T p.L244= (on ENST00000256246; = p.L627= on NM_001350162.2) | Silent (SNP) | VAF 7/153 reads (5%) | called by muse, mutect2
- TIAM2 | c.3288T>C p.D1096= | Silent (SNP) | VAF 11/122 reads (9%) | catalogued as COSV99265092; called by muse, mutect2
- TOX2 | c.1449A>G p.K483= (on ENST00000358131 / NM_001098798.2; = p.K459= on NM_032883.3) | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as COSV100363371; called by muse, mutect2, varscan2
- USF3 | c.3531A>G p.K1177= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as COSV100324734; called by muse, mutect2, varscan2
- USH2A | c.6600C>T p.F2200= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV100229264; called by muse, mutect2, varscan2
- VPS8 | c.2808C>A p.V936= (on ENST00000625842 / NM_001349294.1; = p.V934= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV99800765; called by muse, mutect2, varscan2
- XDH | c.91A>C p.R31= | Silent (SNP) | VAF 63/129 reads (49%) | catalogued as COSV101052007; called by muse, mutect2, varscan2
- ZKSCAN4 | c.360C>T p.S120= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as COSV101043364; called by muse, mutect2, varscan2
- ZNF283 | c.561T>G p.S187= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100190338; called by muse, mutect2, varscan2
- ZNF420 | c.1395T>C p.H465= | Silent (SNP) | VAF 9/123 reads (7%) | catalogued as rs1028959878, COSV100421154; called by muse, mutect2
- ZNF568 | c.1050T>C p.I350= | Silent (SNP) | VAF 49/153 reads (32%) | catalogued as COSV100451171; called by muse, mutect2, varscan2
- ZNF578 | c.1299T>C p.G433= | Silent (SNP) | VAF 47/155 reads (30%) | catalogued as rs878876817, COSV101405009; called by muse, mutect2, varscan2
- ZNF710 | c.879G>A p.K293= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as rs773016303, COSV99184085; called by muse, mutect2, varscan2
- AC005863.1 | n.331A>G | RNA (SNP) | VAF 64/129 reads (50%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498989 T>C | 5'Flank (SNP) | VAF 22/254 reads (9%) | catalogued as rs754397792; called by muse, mutect2
- AP2A2 | c.*364G>A | 3'UTR (SNP) | VAF 11/23 reads (48%) | catalogued as rs772783973, COSV100172507; called by muse, mutect2, varscan2
- ARHGAP42 | c.*3806C>G | 3'UTR (SNP) | VAF 57/175 reads (33%) | catalogued as COSV100081658; called by muse, mutect2, varscan2
- CACNA1C | c.2853+197T>G | Intron (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100215534; called by muse, mutect2, varscan2
- CCDC140 | n.852G>T | RNA (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99734950; called by muse, mutect2, varscan2
- DUSP4 | c.433+4325A>T | Intron (SNP) | VAF 40/125 reads (32%) | catalogued as COSV99529597; called by muse, mutect2, varscan2
- EIF4H | c.469+949A>C | Intron (SNP) | VAF 41/175 reads (23%) | catalogued as COSV99733270; called by muse, mutect2, varscan2
- EPB41L4B | c.1409+1856G>C | Intron (SNP) | VAF 16/176 reads (9%) | catalogued as COSV101000451; called by muse, mutect2
- MIR519A1 | n.47G>T | RNA (SNP) | VAF 17/320 reads (5%) | called by muse, mutect2
- NRG1 | c.1269-504G>T | Intron (SNP) | VAF 38/149 reads (26%) | catalogued as COSV99827700; called by muse, mutect2, varscan2
- SCML4 | c.973+24T>C | Intron (SNP) | VAF 28/230 reads (12%) | catalogued as COSV100940155; called by muse, mutect2, varscan2
- SGIP1 | c.99+999dup | Intron (INS) | VAF 13/26 reads (50%) | catalogued as rs745636084; called by mutect2, varscan2
- WT1 | chr11:32439143 G>A | 5'Flank (SNP) | VAF 13/23 reads (57%) | catalogued as rs1255872715; called by muse, mutect2, varscan2
- ZBTB26 | c.-1A>C | 5'UTR (SNP) | VAF 18/64 reads (28%) | catalogued as COSV101021013; called by muse, mutect2, varscan2
- ZNF322P1 | n.110A>C | RNA (SNP) | VAF 26/378 reads (7%) | called by muse, mutect2
- ZNF436 | c.-157A>G | 5'UTR (SNP) | VAF 54/110 reads (49%) | called by muse, varscan2
- ZNF436 | c.-210A>G | 5'UTR (SNP) | VAF 36/114 reads (32%) | called by muse, varscan2
